Surgical pathology report (de-identified scan), TCGA case TCGA-44-2659, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-2659-01A (Primary Tumor).

SPECIMEN

- A. Left lower lobe
- B. Left upper lobe
- C. Level 7
- D. Level 6
- E. Level 5
- F. Level 4

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung nodule.

FROZEN SECTION DIAGNOSIS

AFS: Left lower lobe, wedge resection: Adenocarcinoma, margin negative.

BFS: Lung left upper lobe, wedge resection - Adenocarcinoma, margin negative.

GROSS DESCRIPTION

A. Labeled with the patient's name, medical record number and "left lower lobe". The specimen consists of a spindle wedge sheet fragment of pulmonary tissue which measures 8.5 x 2 x 2 cm in greatest dimension. A staple line is present along the largest margin measuring 8 cm. The specimen is incised and is found to contain a well circumscribed firm tan nodule which measures up to 1.7 cm in diameter. A portion of this nodule is submitted for tissue procurement. The remainder of the tissue is submitted as per block summary: AFS, A1, A2 - entire nodule following procurement; A3 - representative sections of pulmonary tissue; A4 - tissue from adjacent to staple line.

B. Container B is labeled "left upper lobe". The specimen consists of a single piece of pulmonary tissue which measures 10 x 5.5 x 5 cm in greatest dimensions. The specimen is incised and is found to contain a well circumscribed firm tan and black nodule which measures 1.8 x 1.5 x 1.5 cm. Representative

GROSS DESCRIPTION

sections as per block summary B1-B4 - nodule entirely submitted; B5 - representative section of adjacent pulmonary tissue,

B6 - tissue from adjacent to stapled surgical margin.

C. Received fresh labeled "level 7" is a 1.5 x 0.5 x 0.4 cm pink-red irregular soft tissue fragment which is bisected and entirely submitted in one cassette. AS-1.

D. Received fresh labeled "level 6" are two pink-tan and fatty tissue fragments which average 0.8 x 0.4 x 0.3 cm.

The specimens are entirely submitted in one cassette. AS-1.

Source: NCI Genomic Data Commons file b4246c5e-ec96-4428-b6b1-156bd11023d2 (TCGA-44-2659.9015AB9C-AD9F-44F1-AF94-3C7BF34F12FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).